Somatic mutation profile of tumor specimen TCGA-HP-A5MZ-01A (aliquot TCGA-HP-A5MZ-01A-21D-A27I-10) from TCGA case TCGA-HP-A5MZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.2 years (22,702 days).
Specimen TCGA-HP-A5MZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1798ebbd-c947-4c3e-8c28-ce2462a98a8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HP-A5MZ-10A (Blood Derived Normal), aliquot TCGA-HP-A5MZ-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a4dfc1e-6ab2-4bf1-8aa2-f36053c8ae4c

The open-access MAF lists 61 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, Nonsense Mutation 2, 3'UTR 2, Intron 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV51939950; called by muse, mutect2, varscan2
- ATP5F1B | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV56261253; called by muse, mutect2, varscan2
- CDON | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54999129; called by muse, mutect2, varscan2
- CEP152 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.162); catalogued as COSV57860556; called by muse, mutect2
- CIB4 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs374300070, COSV56601515; called by muse, mutect2, varscan2
- COPG1 | c.2083G>T p.A695S | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.154); catalogued as COSV59114647; called by mutect2, varscan2
- DNAH12 | c.6464A>G p.H2155R (on ENST00000351747; = p.H2174R on NM_001366028.2) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV61060999; called by muse, mutect2, varscan2
- DOCK1 | c.3757G>A p.V1253M | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV54744787; called by muse, mutect2
- EHMT2 | c.2797G>A p.V933M | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs146726232; called by muse, mutect2, varscan2
- EPB41L1 | c.1976G>T p.R659L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV52438548, COSV52439236; called by muse, mutect2, varscan2
- ETAA1 | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV55473588; called by muse, mutect2, varscan2
- FECH | c.734T>A p.L245Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM042047, COSV50491331; called by muse, mutect2, varscan2
- FLOT1 | c.880C>G p.L294V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.291); catalogued as COSV64508545; called by muse, mutect2
- GABBR2 | c.324C>T p.C108= | Splice Region (SNP) | VAF 19/101 reads (19%) | catalogued as rs145095054; called by muse, mutect2, varscan2
- IMPG1 | c.580C>A p.L194I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV64058896; called by muse, mutect2, varscan2
- ITPR2 | c.1622T>G p.L541R | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67270908; called by muse, mutect2, varscan2
- ITSN1 | c.2512G>T p.V838L | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.028); catalogued as COSV66083873; called by muse, mutect2, varscan2
- KMT2B | c.4534G>A p.D1512N | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1456547984, COSV55863206; called by muse, mutect2, varscan2
- KRT33A | c.923G>A p.S308N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as rs371555388; called by muse, mutect2, varscan2
- KRT36 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 26/193 reads (13%) | catalogued as COSV60203683; called by muse, mutect2, varscan2
- LRRC8E | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.178); catalogued as rs1182964012, COSV60716836; called by muse, mutect2, varscan2
- NUBPL | c.548A>G p.D183G | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55270055; called by muse, mutect2, varscan2
- NUP98 | c.2567C>T p.S856L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61429202, COSV61433800; called by mutect2, varscan2
- PMS1 | c.2668A>G p.M890V | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV59717177, COSV59720324; called by muse, mutect2, varscan2
- PPP5C | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.113); catalogued as COSV50140746; called by muse, mutect2, varscan2
- RAB4A | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 19/138 reads (14%) | catalogued as COSV64207656; called by muse, mutect2, varscan2
- SDK1 | c.6107A>G p.K2036R | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV67373979; called by muse, mutect2, varscan2
- SLC10A7 | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV53886180; called by muse, mutect2, varscan2
- SLC22A5 | c.765C>G p.D255E | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV55373366; called by muse, mutect2, varscan2
- SPATA13 | c.745A>G p.M249V | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV57978365; called by muse, mutect2, varscan2
- TBC1D32 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV51545853; called by muse, mutect2, varscan2
- THRSP | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.232); catalogued as rs1289448165, COSV55246673; called by muse, mutect2, varscan2
- TPH2 | c.1081A>T p.T361S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as COSV61592576; called by muse, mutect2, varscan2
- TUBB4A | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.908); catalogued as rs1323470395, COSV51157306; called by muse, mutect2, varscan2
- UBA7 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV61092491; called by muse, mutect2, varscan2
- VWC2 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs780603854, COSV61486679; called by mutect2, varscan2
- ZFPM2 | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs756076552, COSV65874257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF337 | c.2037C>G p.H679Q | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs1009380190, COSV53321856; called by muse, mutect2, varscan2
- AHNAK | c.15780del p.S5261Lfs*6 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- CIRBP | c.450del p.Y151Tfs*38 | Frame Shift Del (DEL) | VAF 66/412 reads (16%) | called by pindel, varscan2
- SENP5 | c.680dup p.L227Ffs*8 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- SRRT | c.43_66del p.K15_D22del | In Frame Del (DEL) | VAF 21/187 reads (11%) | called by mutect2, pindel
- ATRNL1 | c.3804T>C p.L1268= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV58093818; called by muse, mutect2
- CUL9 | c.2931C>A p.P977= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV52729550, COSV52730082; called by muse, mutect2, varscan2
- DMBT1 | c.315G>A p.V105= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV57547618; called by muse, mutect2
- EXOC5 | c.1017A>G p.K339= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV61771108; called by muse, mutect2
- GDPD5 | c.1513C>T p.L505= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as rs1161929688, COSV61128308; called by muse, mutect2, varscan2
- GJD2 | c.756C>T p.V252= | Silent (SNP) | VAF 34/254 reads (13%) | catalogued as COSV51748655; called by muse, mutect2, varscan2
- LEFTY1 | c.201C>T p.R67= | Silent (SNP) | VAF 60/126 reads (48%) | called by muse, varscan2
- LPA | c.5346C>T p.C1782= | Silent (SNP) | VAF 6/130 reads (5%) | catalogued as COSV60303889; called by muse, mutect2
- LRRC58 | c.366C>A p.L122= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV55230451; called by muse, mutect2, varscan2
- MPDZ | c.4503T>C p.D1501= | Silent (SNP) | VAF 25/142 reads (18%) | catalogued as rs776038550, COSV59919265; called by muse, mutect2, varscan2
- SLC5A5 | c.1680G>A p.P560= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs149937279; called by muse, mutect2, varscan2
- THRSP | c.18G>A p.K6= | Silent (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- USP4 | c.2400C>T p.P800= | Silent (SNP) | VAF 34/233 reads (15%) | catalogued as COSV55537794; called by muse, mutect2, varscan2
- ZNF84 | c.519T>A p.T173= | Silent (SNP) | VAF 13/73 reads (18%) | called by muse, mutect2, varscan2
- DPP6 | c.244-140702G>T | Intron (SNP) | VAF 16/84 reads (19%) | catalogued as COSV59621944; called by muse, mutect2, varscan2
- ELOA2 | c.-157C>G | 5'UTR (SNP) | VAF 11/88 reads (13%) | catalogued as COSV99796564; called by muse, mutect2, varscan2
- KCNE4 | c.*2189G>A | 3'UTR (SNP) | VAF 3/44 reads (7%) | catalogued as rs993205262, COSV99918953; called by muse, mutect2
- LARP7 | c.1142+397A>G | Intron (SNP) | VAF 28/145 reads (19%) | catalogued as COSV60521289; called by muse, mutect2, varscan2
- SOCS6 | c.*1596T>G | 3'UTR (SNP) | VAF 12/72 reads (17%) | catalogued as COSV101205758; called by muse, mutect2, varscan2
